Surgical pathology report (de-identified scan), TCGA case TCGA-29-1764, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1764-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1764

Surg Path

CLINICAL HISTORY:

Malignant neoplasm, ovary. [REDACTED] with CA125=903.

GROSS EXAMINATION:

A. "Right adnexa (AF1)", received fresh for frozen section. In the container is a 40 gram specimen consisting of a 6.5 x 1.5 cm fallopian tube, 4 x 3 x 1.4 cm ovary and 4.7 x 3.7 x 1.0 detached aggregate of tan hemorrhagic papillary fragments of tissue. The surface of the ovary and fallopian tube are covered in hemorrhagic fibrous adhesions. In addition, sectioning of the ovary demonstrates a 0.7 x 0.6 x 0.5 cm white firm mass immediately beneath the surface epithelium with overlying surface excrescences. Representatives of ovary and detached tissue were frozen as AF1.

BLOCK SUMMARY:

- A1- frozen remnant
- A2-3- ovary with tumor
- A4- fallopian tube with fibrous adhesions
- A5- additional representative of detached tissue

B. "Left tube and ovary", received fresh and placed in formalin. A 16.29 gram adnexa consists of a 3 x 2.5 x 1.0 cm ovary and 5.0 cm long, 1.0 cm in diameter fimbriated fallopian tube. The surface of the ovary and fallopian tube are covered in hemorrhagic fibrous adhesions. In addition, numerous tan friable tumor nodule are identified on the surface of the ovary and between the ovary and fallopian tube. Sectioning of the ovary demonstrates a 0.7 x 0.5 x 0.5 cm firm white nodule immediately beneath the surface.

BLOCK SUMMARY:

- B1- ovary with excrescences
- B2- ovary with mass
- B3- fallopian tube with excrescences

C. "Omental tumor", received fresh and placed in formalin. A 15 x 11 x 3 cm aggregate of fibroadipose tissue is received encased entirely in a friable tan-white papillary tumor. Representative in C1 and C2.

D. "Uterus", received fresh and placed in formalin. A 70 gram, 6.5 x 5.5 x 5.0 cm uterus with a 0.2 cm external os opening contains numerous tumor implants and hemorrhagic fibrous adhesions on the serosa. Sectioning demonstrates a 1.5 x 0.7 x 0.2 cm pedunculated tan endometrial polyp anteriorly. The 2.0 cm long endocervical canal is grossly unremarkable. The squamocolumnar junction is distinct. The ectocervix demonstrates patchy petechial hemorrhages. Tumor extends from the serosa 1.2 cm into the 1.5 cm thick posterior myometrium. In addition seven intramural and submucosal leiomyomata from 0.3 to 2.5 cm in diameter are identified.

BLOCK SUMMARY:

- D1- endometrial polyp
- D2-3- posterior endomyometrium with tumor and leiomyoma
- D4- posterior cervix
- D5- anterior endomyometrium
- D6- anterior cervix

// slides to

[page 2 of 2]
TCGA-29-1764

INTRA OPERATIVE CONSULTATION:

A. "Right adnexa": AFl-carcinoma present

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY, OMENTECTOMY.

PATHOLOGIC STAGE: pT3cNXMX (peritoneal primary)

NOTE:

Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation purposes by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "RIGHT ADNEXA" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE WITH SEROSAL IMPLANTS OF SEROUS PAPILLARY ADENOCARCINOMA, SEE COMMENT.

B. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE WITH SEROSAL IMPLANTS OF SEROUS PAPILLARY ADENOCARCINOMA, SEE COMMENT.

C. "OMENTAL TUMOR":

SEROUS PAPILLARY ADENOCARCINOMA OF THE PERITONEUM, SEE COMMENT.

HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED (GRADE 2).

TUMOR SIZE: 15 CM.

D. "UTERUS" (HYSTERECTOMY):

UTERUS (70 GRAMS):

ENDOMETRIUM: INACTIVE, ENDOMETRIAL POLYP:

MYOMETRIUM: LEIOMYOMATA (LARGEST 2.5 CM).

CERVIX: FREE OF TUMOR.

SEROA: EXTENSIVE IMPLANTS OF ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

COMMENT:

The ovaries show primarily surface involvement by tumor, with less than 5 mm of parenchymal involvement. This meets the [REDACTED] criteria for a diagnosis of primary peritoneal carcinoma.

[REDACTED]

Source: NCI Genomic Data Commons file 538b22d0-e6d9-4d6c-ba57-caeb4b0e1df0 (TCGA-29-1764.3BAE7A57-63D7-4770-A960-CD8F0749CA17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).